Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A64X, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A64X-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

A. Brain, right frontal mass, resection: Anaplastic astrocytoma (WHO grade III), fibrillary type.

Immunohistochemical stains:

p53: Overexpressed in the majority of the tumor cells.

Ki67/MIB1: Low to moderate proliferative index.

IDH1(R132H): Positive.

Seen in consultation with Dr

Interpreted by:

Report electronically signed by:

Transcribed by:

ICD-O-3

Astrocytoma, anaplastic
9401/3

Site @ Brain, frontal lobe
C71.1

Brain, supratentorial
C71.0

JW 5/10/13

Preliminary Frozen Section Consultation:

A. Brain, right frontal mass, smears: Low-grade glial neoplasm. Hold over for evaluation and workup on permanent sections.

Intraoperative cytologic smear(s) interpretation performed by:

[page 2 of 2]
Gross Description:

A. Received fresh labeled "right frontal mass" is a 6.4 x 5.8 x 1.5 cm portion of brain. Smears prepared. Representative sections are submitted. Grossed by

Block Summary:

Part A: Right frontal mass

- 1 Rt frontal brain 1
- 2 Rt frontal brain 2
- 3 Rt frontal brain 3
- 4 Rt frontal brain 4

END OF REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file dc748918-4b96-491a-92a7-d9d32250a714 (TCGA-DB-A64X.2B5E76F9-FEC7-4238-AF98-BEDD20CD8731.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).